CGCI case BLGSP-71-23-00410 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6cdebd29-aa3e-4fd1-8bc3-4dc132a6aeac

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 6 years; Vital status: Dead; Days to death: 201 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 6.6 years (2,412 days); Year of diagnosis: 2016; Method of diagnosis: Surgical Resection; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 201 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Other; Sites of involvement: Small intestine / Kidney, NOS / Brain, NOS / Tongue.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Mesenteric; Tumor largest dimension diameter: 6.1 cm.
   Pathology details: Lymph node involved site: Splenic.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 40; ECOG performance status: 3.
- Days to follow up: 154 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Nervous system, NOS; Days to recurrence: 154 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 201 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Lactate Dehydrogenase 543 [Blood test normal range upper: 590].

Other clinical attributes
- Day 0: Weight: 22.4 kg; Height: 115 cm; BMI: 16.9.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00410-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00410-01A-01-S1-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-23-00410-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-23-00410-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00410-01B-S2-HE: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 50; Percent neutrophil infiltration: 10.
  Slide BLGSP-71-23-00410-01B-S1-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 50; Percent neutrophil infiltration: 10.
- Sample BLGSP-71-23-00410-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00410-01-BCL6: Tissue microarray coordinates: B2,F3,B5.
  Slide BLGSP-71-23-00410-01-BCL2: Tissue microarray coordinates: B2,F3,B5.
  Slide BLGSP-71-23-00410-01-Ki67: Tissue microarray coordinates: B2,F3,B5.
  Slide BLGSP-71-23-00410-01-CD20: Tissue microarray coordinates: B2,F3,B5.
  Slide BLGSP-71-23-00410-01-HE-1: Tissue microarray coordinates: B2,F3,B5.
  Slide BLGSP-71-23-00410-01-CD10: Tissue microarray coordinates: B2,F3,B5.
  Slide BLGSP-71-23-00410-01-CD3: Tissue microarray coordinates: B2,F3,B5.
- Sample BLGSP-71-23-00410-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00410-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 70; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 3; Extranodal involvment other: parietal and tongue; Method initial path diagnosis: Other method, specify:.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 543; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site other: CNS; New tumor event diagnosis evidence: Convincing Imaging; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
